MMRF case MMRF_1834 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f7e1c3b5-5120-4e07-a60d-498c2bd84573

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.4 years (23,524 days); ISS stage: II; Days to last known disease status: 940 days (2.6 years); Days to last follow up: 940 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 69 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 145 days; Days to treatment end: 145 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 147 days; Days to treatment end: 147 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 222 days; Days to treatment end: 940 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.253 mg/dL; Immunoglobulin G 48.4 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.89 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 10.6 g/dL; Glucose 10.8 mmol/L.
- Day 107 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.579 mg/dL; Immunoglobulin G 9.54 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 7.98 mmol/L.
- Day 183 (ECOG 1): M Protein 0.5 g/dL; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 7.04 mmol/L.
- Day 331 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.654 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 0.66 g/L; Beta 2 Microglobulin 1.56 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 364 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 9.13 mmol/L.
- Day 423 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.585 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 7.1 g/dL; Glucose 15.1 mmol/L.
- Day 513 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 5.83 g/L; Immunoglobulin A 0.93 g/L; Beta 2 Microglobulin 1.58 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 576 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.938 mg/dL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 6.82 mmol/L.
- Day 766 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 6.71 mmol/L.
- Day 940 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 7.43 mmol/L.

Other clinical attributes
- Day 1: Weight: 73 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample MMRF_1834_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1834_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
